TCGA case TCGA-2G-AAGB — Testicular Germ Cell Tumors (TCGA-TGCT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Germ Cell Neoplasms; Primary site: Testis. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fe97c0d6-0768-417d-8118-05368e3d4f46

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Netherlands; Age at index: 25 years; Year of birth: 1982; Vital status: Alive.

Diagnoses (1)
1. Embryonal carcinoma, NOS: ICD-O-3 morphology code: 9070/3; ICD-10 code: C62.9; Tissue or organ of origin: Testis, NOS; Site of resection or biopsy: Testis, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 25.5 years (9,319 days); Year of diagnosis: 2008; Method of diagnosis: Orchiectomy; AJCC staging edition: 6th; AJCC clinical T: T4; AJCC clinical N: N2; AJCC clinical M: M1b; AJCC clinical stage: Stage IIIC; AJCC pathologic T: T4; AJCC pathologic N: NX; AJCC pathologic M: M1b; AJCC pathologic stage: Stage IIIC; IGCCCG stage: Poor Prognosis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 2,556 days (7.0 years); Ajcc serum tumor markers: S2; Sites of involvement: Rete Testis / Tunica Albuginea.
   Pathology details: Lymph node dissection site: Retroperitoneal; Lymph nodes removed: No; Timepoint category: Postoperative.
   Pathology details: Intratubular germ cell neoplasia present: Yes; Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bleomycin + Cisplatin + Etoposide; Treatment intent type: Adjuvant; Days to treatment start: 7 days; Days to treatment end: 74 days; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Testis.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 1,821 days (5.0 years); Disease response: Tumor Free.
- Days to follow up: 2,556 days (7.0 years); Disease response: Tumor Free.
- Karnofsky performance status: 80; ECOG performance status: 0; Timepoint: Follow-up.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -3: Lactate Dehydrogenase 401; Alpha Fetoprotein 1946; Human Chorionic Gonadotropin 199.
- Day 7: Lactate Dehydrogenase 370; Alpha Fetoprotein 1251; Human Chorionic Gonadotropin 174.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Fertility history: Did not attempt to reproduce; Undescended testis history: No.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-2G-AAGB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 130 mg.
  Slide TCGA-2G-AAGB-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 20; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 2.
- Sample TCGA-2G-AAGB-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-2G-AAGB-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
